Gene-level copy-number profile of tumor specimen TCGA-2Z-A9JM-01A from TCGA case TCGA-2Z-A9JM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 28.3 years (10,323 days).
Specimen TCGA-2Z-A9JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.04358d2c-d409-4ca1-9748-589470b04a7b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9JM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/31e4daf9-6fe9-42fe-86e1-82e29bd4a8c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,733; copy number 2: 45,608; copy number 3: 7,305; copy number 4: 2,535; copy number 5: 1,075.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9JM-01A-12D-A42I-01): tumor purity 0.65, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,075 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:9,082,557–26,617,295, 223 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:51,716,657–71,713,600, 403 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:72,558,744–86,217,733, 244 genes, copy number 5 (broad region; genes not listed).
- chr7:94,495,299–98,629,869, 77 genes, copy number 5 (broad region; genes not listed).
- chr7:106,035,798–106,315,743, 7 genes, copy number 5: AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2.
- chr7:117,275,451–128,207,943, 121 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
